Somatic mutation profile of tumor specimen TCGA-AP-A0LT-01A (aliquot TCGA-AP-A0LT-01A-11W-A062-09) from TCGA case TCGA-AP-A0LT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 57.8 years (21,107 days).
Specimen TCGA-AP-A0LT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34ef01ea-61af-443d-8b62-ba08e9badef3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LT-10A (Blood Derived Normal), aliquot TCGA-AP-A0LT-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1785a90a-4c0e-4b65-9004-aba9a3b9c79d

The open-access MAF lists 818 somatic variants for this specimen: 629 protein-altering or splice-affecting, 166 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 387, Frame Shift Del 173, Silent 166, Nonsense Mutation 28, Frame Shift Ins 20, Splice Site 10, Intron 9, Splice Region 5, 5'UTR 4, Translation Start Site 3, In Frame Del 3, RNA 3.

Variants (750 of 818; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.2947del p.I983Lfs*2 | Frame Shift Del (DEL) | VAF 43/127 reads (34%) | catalogued as rs774684620; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CDC45 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs540900837, COSV54243701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 58/153 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 87/220 reads (40%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 96/210 reads (46%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 36/87 reads (41%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- WDR19 | c.641del p.L214* | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- ZNF862 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1444761945, COSV56222957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4559+2T>C p.X1520_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | catalogued as COSV66064173; called by muse, mutect2, varscan2
- ABCB1 | c.2674G>T p.G892C | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV55946041; called by muse, mutect2
- ABCB6 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs772193917, COSV54693396; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs749606695; called by mutect2, varscan2
- ACAN | c.6917del p.P2306Lfs*10 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs777726601; called by mutect2, pindel, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs751325833; called by mutect2, pindel, varscan2
- ACTL6A | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66998633; called by muse, mutect2, varscan2
- ACY3 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54828183; called by muse, mutect2, varscan2
- ADAT1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758691072, COSV57185397; called by muse, mutect2, varscan2
- ADGRA3 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51560602; called by muse, mutect2
- AGBL2 | c.2482del p.L828Wfs*8 | Frame Shift Del (DEL) | VAF 48/180 reads (27%) | catalogued as rs1310675921; called by mutect2, pindel, varscan2
- AGMAT | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65435634; called by muse, mutect2, varscan2
- AGTR1 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV62557398, COSV62558866; called by muse, mutect2, varscan2
- ALK | c.1274G>A p.C425Y | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1318224093, COSV66558955; called by muse, mutect2, varscan2
- ANKH | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52477617; called by muse, mutect2, varscan2
- ANKRD12 | c.4577del p.N1526Mfs*10 | Frame Shift Del (DEL) | VAF 82/163 reads (50%) | catalogued as rs768306357; called by mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD50 | c.4109A>G p.Q1370R | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.901); catalogued as COSV72385127; called by muse, mutect2, varscan2
- AP1G1 | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV55486109; called by muse, mutect2
- APLNR | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV57241575; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGEF2 | c.3608C>T p.A1203V | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760639976, COSV64210834; called by muse, mutect2, varscan2
- ARHGAP11B | c.663C>T p.G221= | Splice Region (SNP) | VAF 183/462 reads (40%) | catalogued as rs778197945, COSV70288298; called by muse, mutect2, varscan2
- ARHGAP33 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.933); catalogued as rs758099274, COSV50119748; called by muse, mutect2, varscan2
- ARHGEF19 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs576557883, COSV54615299; called by muse, mutect2, varscan2
- ARID5B | c.44T>C p.L15S | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV54415026; called by muse, varscan2
- ASB6 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52964494; called by muse, mutect2, varscan2
- ASNSD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53623007; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 70/168 reads (42%) | catalogued as rs746676748; called by mutect2, varscan2
- ATF7 | c.1256A>G p.Q419R (on ENST00000548446 / NM_001366555.2; = p.Q408R on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV60642392; called by muse, mutect2, varscan2
- ATL1 | c.1111del p.M371Wfs*29 | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | catalogued as rs1566733927; called by mutect2, pindel, varscan2
- ATM | c.6185C>T p.A2062V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.056); catalogued as COSV53728957; called by muse, mutect2, varscan2
- ATM | c.8558C>T p.T2853M | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141534716, CM157957, COSV53759103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV63514187; called by muse, mutect2, varscan2
- ATP10B | c.49A>G p.R17G | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV58777911, COSV58781152; called by muse, mutect2, varscan2
- ATXN1 | c.858del p.S287Pfs*38 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs774055637, COSV104392095; called by mutect2, varscan2
- AXIN1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV51984069; called by muse, mutect2, varscan2
- AZGP1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377632165; called by muse, mutect2, varscan2
- B3GNT4 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57335869; called by muse, mutect2, varscan2
- BCAN | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61255699; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 64/157 reads (41%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND4 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV72468957; called by muse, varscan2
- BEX2 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 125/293 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV65500671; called by muse, mutect2, varscan2
- BIRC6 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); catalogued as COSV70196088; called by muse, mutect2, varscan2
- BMPER | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51812574; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- C5 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV56324442; called by muse, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 50/110 reads (45%) | catalogued as rs763603775; called by mutect2, varscan2
- CAB39 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV51474628; called by muse, mutect2, varscan2
- CAP2 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV57730371; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel
- CBLB | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV51422183; called by muse, mutect2, varscan2
- CCDC150 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs61745387, COSV55872221; called by muse, mutect2
- CCDC88A | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as COSV55057161; called by muse, mutect2, varscan2
- CD22 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as COSV50049809; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 84/241 reads (35%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDH1 | c.1997A>G p.N666S | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as rs897830106, COSV55728349; called by muse, mutect2, varscan2
- CDH23 | c.7748C>T p.A2583V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1235030095, COSV56450527; called by muse, mutect2, varscan2
- CDH26 | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV54843447; called by muse, mutect2, varscan2
- CDH7 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59882284; called by muse, mutect2, varscan2
- CDK16 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766783076, COSV52091191; called by muse, mutect2, varscan2
- CDKN1B | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV57429732; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs773511514; called by mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 55/115 reads (48%) | catalogued as rs763090473; called by mutect2, varscan2
- CELSR2 | c.8111G>A p.S2704N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs931513214, COSV54767671; called by muse, mutect2, varscan2
- CEP104 | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770522288, COSV65516354; called by muse, mutect2, varscan2
- CFAP58 | c.695T>C p.M232T | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV57211425; called by muse, mutect2, varscan2
- CFL2 | c.311+1G>A p.X104_splice | Splice Site (SNP) | VAF 26/63 reads (41%) | catalogued as rs1014929507, COSV53311044; called by muse, mutect2, varscan2
- CHD7 | c.7145C>T p.T2382M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs189926848, COSV71107549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.8789C>T p.A2930V | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV71107550; called by muse, mutect2, varscan2
- CHRND | c.1418G>A p.C473Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51317526; called by muse, mutect2, varscan2
- CHST10 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 89/197 reads (45%) | catalogued as COSV51804345, COSV51804926; called by muse, mutect2, varscan2
- CIITA | c.2122T>G p.F708V | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60854523; called by muse, mutect2, varscan2
- CLCN5 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56582599; called by muse, mutect2, varscan2
- CLEC10A | c.754G>A p.D252N (on ENST00000254868 / NM_182906.4; = p.D228N on NM_006344.4) | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1235082203, COSV54700356; called by muse, mutect2, varscan2
- CLEC16A | c.3098C>G p.A1033G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV55488665, COSV55488767; called by muse, mutect2, varscan2
- CNKSR1 | c.1540C>T p.R514* (on ENST00000374253 / NM_001297647.2; = p.R507* on NM_006314.3) | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs762261953, COSV58792410; called by muse, mutect2, varscan2
- CNOT4 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as COSV59650132; called by muse, mutect2, varscan2
- COL11A2 | c.1427C>T p.A476V (on ENST00000341947 / NM_080680.3; = p.A369V on NM_080679.2) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373983482, COSV59494064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV57325681; called by muse, mutect2, varscan2
- COPS5 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV63474176; called by muse, varscan2
- CORO1B | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs545641837, COSV58168221; called by muse, mutect2, varscan2
- COX7A1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53084337; called by muse, mutect2, varscan2
- CPSF2 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as rs998257533, COSV54097255; called by muse, mutect2, varscan2
- CPXM1 | c.1628T>C p.M543T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs753359247, COSV66044713; called by muse, mutect2, varscan2
- CRNN | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 149/323 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs759055380, COSV55120916; called by muse, mutect2, varscan2
- CSF2RB | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.196); catalogued as rs770169752, COSV53255913; called by muse, varscan2
- CSMD2 | c.3980G>A p.R1327H | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs772219815, COSV53884902; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as rs766438669; called by mutect2, varscan2
- CSNK1A1L | c.690del p.K230Nfs*31 | Frame Shift Del (DEL) | VAF 74/218 reads (34%) | catalogued as rs369743261; called by mutect2, pindel, varscan2
- CTNNAL1 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1490320873, COSV57701604, COSV57705103; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTRC | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV65621223; called by muse, mutect2, varscan2
- CUL7 | c.3774G>T p.L1258F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54813626; called by muse, mutect2, varscan2
- CWC22 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748093590, COSV55427056; called by muse, mutect2
- CYB5D1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV54678326; called by muse, mutect2, varscan2
- CYP11A1 | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV51430820; called by muse, mutect2, varscan2
- CYP46A1 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV55893268; called by muse, mutect2, varscan2
- DCAF5 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 49/95 reads (52%) | catalogued as COSV58458695; called by muse, mutect2, varscan2
- DCHS1 | c.6976C>T p.R2326C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773714208, COSV55031379; called by muse, mutect2, varscan2
- DCPS | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV55010137; called by muse, mutect2, varscan2
- DDX27 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs780574398, COSV65629086; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 48/112 reads (43%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX39A | c.308T>A p.L103Q | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54390612; called by muse, mutect2, varscan2
- DDX53 | c.1744T>A p.L582M | Missense Mutation (SNP) | VAF 93/213 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60068570; called by muse, mutect2, varscan2
- DEDD | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV63501232; called by muse, mutect2, varscan2
- DGKD | c.650C>T p.T217I (on ENST00000264057 / NM_152879.3; = p.T173I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV51034396; called by muse, mutect2, varscan2
- DGKK | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1557223900, COSV65706566; called by muse, mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs771360300; called by mutect2, varscan2
- DIAPH3 | c.3055del p.R1019Efs*12 (on ENST00000400324 / NM_001042517.2; = p.R756Efs*12 on NM_030932.3) | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs753024929; called by mutect2, pindel, varscan2
- DIO1 | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.652); catalogued as COSV50776520; called by muse, mutect2
- DNAJB9 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1240323337, COSV50811924; called by muse, mutect2, varscan2
- DONSON | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51651777; called by muse, mutect2, varscan2
- DST | c.21781A>G p.T7261A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs988645754, COSV55000510; called by muse, mutect2, varscan2
- DST | c.7888del p.A2630Pfs*4 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as COSV55000514; called by mutect2, pindel, varscan2
- DVL3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs746606032, COSV57455023; called by muse, mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 69/178 reads (39%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- DYNC1H1 | c.9496G>A p.G3166S | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as rs1393341368, COSV64134768; called by muse, mutect2, varscan2
- ECI2 | c.1072G>A p.E358K (on ENST00000380118 / NM_206836.3; = p.E328K on NM_006117.2) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs1012753901, COSV60985294; called by muse, mutect2, varscan2
- EIF3M | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV60072279; called by muse, mutect2, varscan2
- EIF4G2 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as rs773483249, COSV60596311; called by muse, mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELAPOR1 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs139753360; called by muse, mutect2, varscan2
- ELMO1 | c.1086+1G>A p.X362_splice | Splice Site (SNP) | VAF 24/65 reads (37%) | catalogued as COSV60296758, COSV60319801; called by muse, mutect2, varscan2
- EMG1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54641183; called by muse, mutect2, varscan2
- ENO3 | c.1099del p.V367* | Frame Shift Del (DEL) | VAF 40/84 reads (48%) | catalogued as rs961001512; called by mutect2, varscan2
- ENPP7 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.144); catalogued as rs781968600, COSV100093782, COSV60385122; called by muse, mutect2, varscan2
- EPHA5 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1370682403, COSV56633477, COSV56668756, COSV56668986; called by muse, mutect2, varscan2
- ESYT2 | c.1099G>A p.V367I (on ENST00000613624; = p.V291I on NM_020728.3) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.391); catalogued as rs373194637; called by muse, mutect2, varscan2
- EXOC1 | c.2482C>A p.L828I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62119241; called by muse, mutect2, varscan2
- FABP5 | c.346T>A p.L116I | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV51917138; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM171A1 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as COSV65313758; called by muse, mutect2, varscan2
- FAM47C | c.2003del p.P668Rfs*157 | Frame Shift Del (DEL) | VAF 43/139 reads (31%) | catalogued as COSV63729354; called by mutect2, pindel, varscan2
- FAT1 | c.10981C>T p.R3661C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71672213; called by muse, mutect2, varscan2
- FAT1 | c.8292G>C p.K2764N | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71672216; called by muse, mutect2, varscan2
- FAT2 | c.4082C>T p.T1361M | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751967199, COSV55814438; called by muse, mutect2
- FBXL17 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62848957; called by muse, mutect2, varscan2
- FBXL7 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61641904, COSV61644880; called by muse, mutect2, varscan2
- FBXO31 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61147846; called by muse, mutect2, varscan2
- FBXW11 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV51605864; called by muse, mutect2, varscan2
- FCMR | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 135/248 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs138175929; called by muse, mutect2, varscan2
- FGD5 | c.3086G>A p.S1029N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV53238368; called by muse, mutect2, varscan2
- FGD5 | c.4291C>T p.L1431F | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778882516, COSV53238388; called by muse, mutect2, varscan2
- FGF23 | c.568del p.L190* | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as COSV52977498, COSV99426436; called by mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLCN | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs748031634, COSV53256804, COSV99550761; ClinVar: uncertain significance; called by muse, mutect2
- FLG | c.11050C>T p.Q3684* | Nonsense Mutation (SNP) | VAF 224/522 reads (43%) | catalogued as rs1175493104, CM071766, COSV64237610; called by muse, mutect2, varscan2
- FLNC | c.2045G>A p.C682Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as rs756904288, COSV57951466; called by muse, mutect2, varscan2
- FMNL1 | c.240del p.A81Qfs*7 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1417594683, COSV100056244; called by mutect2, pindel, varscan2
- FPGS | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1182040267, COSV64675326; called by muse, mutect2, varscan2
- FRAS1 | c.11142T>A p.N3714K | Missense Mutation (SNP) | VAF 81/152 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.744); catalogued as COSV53593263; called by muse, mutect2, varscan2
- FRG1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs75585360, COSV56995045; called by muse, mutect2
- FYCO1 | c.3832G>A p.A1278T | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1025398210, COSV56113995; called by muse, mutect2, varscan2
- GALNT11 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as rs766807653, COSV57424702; called by muse, mutect2, varscan2
- GAPVD1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.956); catalogued as COSV52920889; called by muse, mutect2, varscan2
- GARRE1 | c.2837G>A p.S946N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV55097008; called by muse, mutect2, varscan2
- GATA6 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV52524650; called by muse, mutect2, varscan2
- GBF1 | c.1886C>G p.T629S (on ENST00000369983 / NM_001377137.1; = p.T628S on NM_004193.3) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV64143132; called by muse, mutect2, varscan2
- GFOD1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs371884277, COSV101015054; called by muse, mutect2, varscan2
- GGN | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV53056166; called by muse, mutect2, varscan2
- GJB2 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV67010529; called by muse, mutect2, varscan2
- GLI3 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV67885695; called by muse, mutect2, varscan2
- GLUD1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as rs780294683, COSV53277606; called by muse, mutect2, varscan2
- GMFB | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771198764, COSV63737617; called by muse, mutect2, varscan2
- GNL3 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV56476711; called by muse, mutect2, varscan2
- GNPDA2 | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.591); catalogued as COSV54946119; called by muse, mutect2, varscan2
- GOLGA5 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1284959632, COSV50832145; called by muse, mutect2, varscan2
- GP5 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59877809; called by muse, mutect2, varscan2
- GPATCH2L | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV55047042; called by muse, mutect2, varscan2
- GPR61 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179323641, COSV68177329; called by muse, mutect2, varscan2
- GPR75 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV61825225; called by muse, mutect2, varscan2
- GPRIN2 | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV65400517; called by muse, mutect2
- GREB1 | c.5816G>T p.R1939L | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs750656652, COSV52181864, COSV52187448; called by muse, mutect2, varscan2
- GRHPR | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as rs369950120; called by muse, mutect2, varscan2
- GRIA2 | c.223A>G p.N75D | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV52383743; called by muse, mutect2, varscan2
- GRWD1 | c.673del p.R225Gfs*2 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs770573431; called by mutect2, pindel, varscan2
- GSS | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as rs375637013; called by muse, mutect2, varscan2
- GSTM4 | c.29T>G p.I10S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58693996; called by muse, mutect2, varscan2
- GUCA1C | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53751509; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as COSV54945907; called by mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 44/110 reads (40%) | catalogued as rs750293240, COSV55140417; called by mutect2, varscan2
- H2AP | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs767109332, COSV61910754, COSV61910791; called by muse, mutect2, varscan2
- H2BC5 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.33); catalogued as COSV56800030; called by muse, mutect2, varscan2
- HARS1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs550778711, COSV56905701; called by muse, mutect2, varscan2
- HDGFL3 | c.147del p.F49Lfs*9 | Frame Shift Del (DEL) | VAF 52/133 reads (39%) | catalogued as rs1567170453; called by mutect2, pindel, varscan2
- HECW1 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs748217507, COSV67823215; called by muse, mutect2, varscan2
- HK1 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 45/89 reads (51%) | catalogued as rs760487849, COSV53854309; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs758463831, COSV54560388; called by muse, varscan2
- HOXA7 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54216818; called by muse, mutect2, varscan2
- HRH1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1408273754, COSV67955072; called by muse, mutect2, varscan2
- HSPH1 | c.1731del p.V578Lfs*12 | Frame Shift Del (DEL) | VAF 33/72 reads (46%) | catalogued as rs750959278, COSV60712362; called by mutect2, varscan2
- ICAM3 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV50328547; called by muse, mutect2, varscan2
- IFIT5 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV65655299; called by muse, mutect2, varscan2
- IFNLR1 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59525329; called by muse, mutect2, varscan2
- IGDCC4 | c.2613del p.T872Qfs*11 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV61539288; called by mutect2, pindel
- IGF2R | c.4841G>A p.C1614Y | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63626787; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV56241008; called by muse, mutect2, varscan2
- IL26 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs751627906, COSV57488380; called by muse, mutect2, varscan2
- INSR | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV57158558; called by muse, mutect2, varscan2
- IP6K1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs772587623, COSV57694951; called by muse, mutect2, varscan2
- IPO4 | c.2157G>T p.E719D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.109); catalogued as COSV61015316; called by muse, mutect2, varscan2
- IPO8 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.224); catalogued as COSV56239891; called by muse, mutect2, varscan2
- IQCE | c.1616dup p.A540Gfs*5 | Frame Shift Ins (INS) | VAF 13/27 reads (48%) | catalogued as rs759821884; called by mutect2, varscan2
- IQCH | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769242387, COSV60049680; called by muse, mutect2, varscan2
- IQSEC1 | c.2636A>G p.Q879R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV56221602; called by muse, mutect2, varscan2
- IRS1 | c.2764A>G p.R922G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.242); catalogued as COSV59334068; called by muse, mutect2, varscan2
- ITGAL | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV63320387; called by muse, mutect2
- ITIH4 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571801; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 62/72 reads (86%) | catalogued as rs755650243; called by mutect2, varscan2
- KANK4 | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV58092078; called by muse, mutect2, varscan2
- KAT7 | c.1643C>T p.T548M | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV52013331; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNG4 | c.1309A>G p.S437G | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57582828; called by muse, mutect2, varscan2
- KCNH6 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs778819571, COSV59001125; called by muse, mutect2, varscan2
- KDM2B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782033254, COSV65638501; called by muse, mutect2, varscan2
- KDM4D | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs369755868; called by muse, mutect2, varscan2
- KIAA1210 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 199/456 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV68175768; called by muse, mutect2, varscan2
- KIAA1549 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 136/283 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV54307015; called by muse, mutect2, varscan2
- KIF21B | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59753143; called by muse, mutect2, varscan2
- KIF24 | c.907A>G p.N303D | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as COSV61453424; called by muse, mutect2, varscan2
- KIF5C | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1456311400, COSV68480036; called by muse, mutect2, varscan2
- KIFAP3 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs759727470, COSV63031319; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 79/244 reads (32%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KIZ | c.619T>G p.C207G | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV55683768; called by muse, mutect2, varscan2
- KLHL9 | c.1464G>A p.M488I | Missense Mutation (SNP) | VAF 163/430 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV62921211; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV55868319; called by mutect2, varscan2
- KMT2C | c.7769A>G p.H2590R | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.153); catalogued as COSV51341772; called by muse, mutect2, varscan2
- KRIT1 | c.1073_1075del p.P358del | In Frame Del (DEL) | VAF 43/113 reads (38%) | catalogued as rs1356206191; called by pindel, varscan2
- KRT1 | c.1174A>T p.R392* | Nonsense Mutation (SNP) | VAF 100/202 reads (50%) | catalogued as COSV52865216; called by muse, mutect2, varscan2
- KRTAP5-1 | c.547T>C p.C183R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.49); catalogued as COSV66298759; called by muse, varscan2
- LAMB2 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs866936474, COSV59731297, COSV59732618; called by muse, mutect2, varscan2
- LAMC3 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs376262461; called by muse, mutect2, varscan2
- LANCL2 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs375166275; called by muse, mutect2, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs746633076; called by mutect2, varscan2
- LCK | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60738802; called by muse, mutect2, varscan2
- LDHC | c.126G>A p.K42= | Splice Region (SNP) | VAF 46/112 reads (41%) | catalogued as rs1486702368, COSV55003406; called by muse, mutect2, varscan2
- LDHC | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55003418; called by muse, mutect2, varscan2
- LEMD3 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752732536, COSV57648731; called by muse, mutect2, varscan2
- LHCGR | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54292576; called by muse, mutect2, varscan2
- LHFPL6 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65443936; called by muse, mutect2, varscan2
- LIG1 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs201176712, COSV54389815; called by muse, mutect2, varscan2
- LIG4 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs747450004, COSV63596494; called by muse, mutect2, varscan2
- LIMK2 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs777847145, COSV59181520; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 176/226 reads (78%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMTK2 | c.767T>C p.M256T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51991340; called by muse, mutect2
- LRP12 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200909989, COSV52626059, COSV52633325; called by muse, mutect2, varscan2
- LRRC17 | c.1138del p.T380Rfs*56 | Frame Shift Del (DEL) | VAF 58/157 reads (37%) | catalogued as rs1366006623; called by mutect2, pindel, varscan2
- LRRC66 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs527846401, COSV100602767, COSV58632301; called by muse, mutect2, varscan2
- LRRC8A | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs754072305, COSV52184366; called by muse, mutect2, varscan2
- LRRK1 | c.5044G>A p.A1682T | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs777107638, COSV52603450, COSV52624529, COSV99441801; called by muse, mutect2, varscan2
- LY6E | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs777594710, COSV52869552; called by muse, mutect2, varscan2
- LYG1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 75/167 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV57915224; called by muse, mutect2, varscan2
- LYPLA2 | c.78G>A p.A26= | Splice Region (SNP) | VAF 42/96 reads (44%) | catalogued as rs2232978, COSV55754537; called by muse, mutect2, varscan2
- LYST | c.6148C>T p.R2050W | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs773494262, COSV67703838; called by muse, mutect2, varscan2
- LZTS1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV56117918, COSV99742896; called by muse, mutect2
- MAP1A | c.1248del p.D417Tfs*48 | Frame Shift Del (DEL) | VAF 18/28 reads (64%) | catalogued as rs1449327112, COSV100289242; called by mutect2, varscan2
- MAP3K21 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV64041120; called by muse, mutect2, varscan2
- MAP3K4 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs995466623, COSV62330492; called by muse, mutect2, varscan2
- MAST1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756908190, COSV52241937; called by muse, mutect2, varscan2
- MAST1 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV52241959; called by muse, mutect2, varscan2
- MBD5 | c.3226G>A p.V1076I | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs973326943, COSV68695905; called by muse, mutect2, varscan2
- MDN1 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750482238, COSV101021890, COSV65517975; called by muse, mutect2, varscan2
- MEGF8 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV52076748; called by muse, mutect2, varscan2
- MICAL1 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1386391874, COSV62192187; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MON1A | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56559489; called by muse, mutect2, varscan2
- MPP6 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs1410589833, COSV56035875; called by muse, mutect2, varscan2
- MRGPRD | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58422847; called by muse, mutect2, varscan2
- MRPL39 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs771380688, COSV56260022; called by muse, mutect2, varscan2
- MRTO4 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs563261309, COSV57673160; called by muse, mutect2
- MS4A13 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs1226655818, COSV65445446; called by muse, mutect2, varscan2
- MSL3 | c.1319del p.P440Qfs*22 (on ENST00000312196 / NM_078629.4; = p.P274Qfs*22 on NM_006800.4) | Frame Shift Del (DEL) | VAF 74/168 reads (44%) | catalogued as rs768515139; called by mutect2, varscan2
- MUC5B | c.9888del p.S3297Pfs*51 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs1317251635; called by mutect2, varscan2
- MYCBPAP | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as rs773750865, COSV60405666; called by muse, mutect2, varscan2
- MYH1 | c.3388C>T p.R1130W | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56844359; called by muse, mutect2, varscan2
- NALCN | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV51920711, COSV51970651; called by muse, mutect2, varscan2
- NAT8 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55542219; called by muse, mutect2, varscan2
- NAV3 | c.5308G>A p.V1770I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57064682; called by muse, mutect2, varscan2
- NBPF1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.866); catalogued as COSV67427098; called by muse, mutect2
- NCK2 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746745967, COSV51888940, COSV51894311; called by muse, mutect2, varscan2
- NDN | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100086175, COSV59358609; called by muse, mutect2, varscan2
- NDUFAF5 | c.761T>C p.L254S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65246567; called by muse, mutect2, varscan2
- NEFM | c.1580A>G p.K527R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV55330746; called by muse, mutect2, varscan2
- NEK9 | c.2206A>G p.N736D | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV53129505; called by muse, mutect2, varscan2
- NELFA | c.1435G>A p.E479K (on ENST00000542778; = p.E468K on NM_005663.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV56387149; called by muse, mutect2, varscan2
- NEURL4 | c.3065G>T p.R1022M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV59747483; called by muse, mutect2, varscan2
- NID1 | c.2753del p.P918Rfs*3 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV51621061; called by mutect2, varscan2
- NLRP12 | c.2188del p.V730* | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs771632319; called by mutect2, pindel, varscan2
- NOL6 | c.1921del p.L641Wfs*8 | Frame Shift Del (DEL) | VAF 121/331 reads (37%) | catalogued as rs1329320091; called by mutect2, pindel, varscan2
- NOTCH1 | c.5852G>A p.S1951N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs758019601, COSV53032395; called by muse, mutect2, varscan2
- NR4A2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs759305222, COSV59892768; called by muse, mutect2, varscan2
- NRDC | c.1766T>C p.V589A | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV61401989; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 47/109 reads (43%) | catalogued as rs776154715; called by mutect2, varscan2
- NRIP1 | c.1926del p.M643Cfs*13 | Frame Shift Del (DEL) | VAF 96/266 reads (36%) | catalogued as COSV59658997; called by mutect2, pindel, varscan2
- NSUN2 | c.2273G>A p.C758Y | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.044); catalogued as rs747294033, COSV52952739; called by muse, mutect2, varscan2
- NUP205 | c.2122del p.C708Afs*77 | Frame Shift Del (DEL) | VAF 91/292 reads (31%) | catalogued as COSV53665219; called by mutect2, pindel, varscan2
- NYNRIN | c.2561C>T p.T854M | Missense Mutation (SNP) | VAF 129/290 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as rs762799957, COSV66841314; called by muse, mutect2, varscan2
- OBSCN | c.15712G>A p.A5238T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52746696; called by muse, mutect2, varscan2
- OBSCN | c.22813G>A p.D7605N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs570370171, COSV62175564; called by muse, mutect2, varscan2
- OBSL1 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs765280401, COSV54703762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 51/146 reads (35%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OCA2 | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747214535, HM080076, COSV62339733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR1A2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 217/483 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs775857630, COSV67936143; called by muse, mutect2, varscan2
- OR1B1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs1191636526, COSV100506520, COSV59171265; called by muse, mutect2, varscan2
- OR2B2 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57579157; called by muse, mutect2, varscan2
- OR52N4 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as rs868159375, COSV57890415; called by muse, mutect2
- OR5H15 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 178/413 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV62947489; called by muse, mutect2, varscan2
- OR5M10 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV73242259, COSV73242387; called by muse, mutect2, varscan2
- PABPC3 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs746078288, COSV55797266; called by muse, mutect2, varscan2
- PACSIN3 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54065339; called by muse, mutect2
- PALMD | c.513A>G p.K171= | Splice Region (SNP) | VAF 21/57 reads (37%) | catalogued as rs751532207, COSV54163132; called by muse, mutect2, varscan2
- PAPOLB | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 121/307 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV68199523; called by muse, mutect2, varscan2
- PASD1 | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.549); catalogued as COSV64854268; called by muse, mutect2, varscan2
- PCBP4 | c.973G>A p.A325T (on ENST00000322099 / NM_033010.2; = p.A282T on NM_020418.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs770277994, COSV59053877; called by muse, mutect2
- PCDHA8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV65335056; called by muse, mutect2, varscan2
- PCDHB16 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV53358550; called by muse, mutect2, varscan2
- PCDHB5 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV50647672; called by muse, mutect2, varscan2
- PCDHB9 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53375934; called by muse, mutect2, varscan2
- PCDHGA3 | c.859A>G p.K287E | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as COSV53906958; called by muse, mutect2, varscan2
- PDE1B | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54489976; called by muse, mutect2, varscan2
- PDZD2 | c.5896A>G p.T1966A | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56852195; called by muse, mutect2, varscan2
- PFKM | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56656230; called by muse, mutect2, varscan2
- PGBD1 | c.1043C>A p.A348D | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV52551548; called by muse, mutect2, varscan2
- PGC | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs749055257, COSV63122135, COSV63122250; called by muse, mutect2, varscan2
- PHACTR4 | c.214C>T p.R72* (on ENST00000373839 / NM_001350159.2; = p.R82* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs1468459755, COSV65783253; called by muse, mutect2, varscan2
- PHF13 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV50010600, COSV99275529; called by muse, mutect2, varscan2
- PHTF2 | c.760G>A p.A254T (on ENST00000248550 / NM_001366089.1; = p.A216T on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.424); catalogued as COSV50323901; called by muse, mutect2, varscan2
- PIGB | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51241202; called by muse, mutect2, varscan2
- PIGL | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750654333, COSV56684004; called by muse, mutect2, varscan2
- PKD1L1 | c.4166C>T p.A1389V | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs552911318, COSV56958995, COSV56964352; called by muse, mutect2, varscan2
- PLEKHG1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746019837, COSV62045417, COSV62046646; called by muse, mutect2, varscan2
- PLEKHG2 | c.2909C>T p.T970I | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.368); catalogued as COSV52678968; called by muse, mutect2, varscan2
- PLXDC2 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs202068068, COSV65901215; called by muse, mutect2, varscan2
- PLXNB1 | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV56487116; called by muse, mutect2, varscan2
- PNN | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53765569; called by muse, mutect2, varscan2
- POLR1A | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV55689757; called by muse, mutect2, varscan2
- POLR1B | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV54495198; called by muse, mutect2, varscan2
- POLR1B | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs768820442, COSV54495212; called by muse, mutect2, varscan2
- POU3F4 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1354177998, COSV64537973; called by muse, mutect2, varscan2
- POU5F2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV67934271; called by muse, mutect2, varscan2
- PPFIA2 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61022247, COSV61032476; called by muse, mutect2, varscan2
- PPP1R13B | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs376044714; called by muse, mutect2, varscan2
- PPP1R16B | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as COSV55374629; called by muse, mutect2, varscan2
- PPP1R3A | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748704853, COSV52877469; called by muse, mutect2, varscan2
- PPP2R5E | c.24_26del p.P9del | In Frame Del (DEL) | VAF 27/58 reads (47%) | catalogued as rs753518402; called by pindel, varscan2
- PPP3CB | c.577A>T p.S193C | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1187107298, COSV61151088; called by muse, mutect2, varscan2
- PPT2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as rs767651019, COSV61353901, COSV61353944; called by muse, mutect2, varscan2
- PRKDC | c.7191T>G p.C2397W | Missense Mutation (SNP) | VAF 112/258 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58044890; called by muse, mutect2, varscan2
- PRPF39 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV63276553; called by muse, mutect2, varscan2
- PTPRG | c.2293T>C p.C765R | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV55630805; called by muse, mutect2, varscan2
- PTPRU | c.3497G>A p.R1166H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1312599704, COSV60522827; called by muse, mutect2, varscan2
- PYM1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1048735592, COSV56811487; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 68/156 reads (44%) | catalogued as rs755727862; called by mutect2, varscan2
- RASGRP2 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1431038254, COSV62448878, COSV62451363; called by muse, mutect2, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs781825075; called by mutect2, pindel, varscan2
- RBM26 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57391746; called by muse, mutect2, varscan2
- RELA | c.1459del p.H487Tfs*7 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as COSV58014427; called by mutect2, pindel, varscan2
- RIC1 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 165/349 reads (47%) | catalogued as COSV52605617; called by muse, mutect2, varscan2
- RIC8A | c.1294G>A p.E432K (on ENST00000526104 / NM_001286134.1; = p.E438K on NM_021932.5) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.488); catalogued as rs372539478; called by muse, mutect2, varscan2
- RIN3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774034330, COSV53645564; called by muse, mutect2, varscan2
- RINT1 | c.740del p.P247Lfs*8 | Frame Shift Del (DEL) | VAF 63/182 reads (35%) | catalogued as rs1352349454; called by mutect2, pindel, varscan2
- RNF123 | c.1629+1del | Frame Shift Del (DEL) | VAF 60/152 reads (39%) | catalogued as COSV59688684; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 47/139 reads (34%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 45/85 reads (53%) | catalogued as COSV60415481; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 34/68 reads (50%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPTN | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 764/1929 reads (40%) | catalogued as COSV60166488; called by muse, mutect2, varscan2
- RSPH10B | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197386723, COSV61755238; called by muse, varscan2
- RYR3 | c.6710del p.G2237Efs*56 (on ENST00000389232; = p.G2237Efs*57 on NM_001036.6) | Frame Shift Del (DEL) | VAF 104/269 reads (39%) | catalogued as rs751516213; called by mutect2, pindel, varscan2
- SAFB | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV52649929; called by muse, mutect2, varscan2
- SCMH1 | c.1427C>T p.T476I (on ENST00000326197 / NM_001031694.2; = p.T429I on NM_012236.4) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV58232783; called by muse, mutect2, varscan2
- SCN4A | c.2227C>T p.H743Y | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV71125766; called by muse, mutect2, varscan2
- SEC13 | c.634A>C p.S212R (on ENST00000350697 / NM_183352.3; = p.S215R on NM_030673.4) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV61601318; called by muse, mutect2, varscan2
- SEC16B | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs201675705; called by muse, mutect2, varscan2
- SEL1L | c.1110del p.G371Vfs*20 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as COSV60921783; called by mutect2, pindel, varscan2
- SEMA4A | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61772171; called by muse, mutect2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINH1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV63997731; called by muse, mutect2, varscan2
- SERPINH1 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63997736; called by muse, mutect2, varscan2
- SETD2 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as COSV57431463; called by muse, mutect2, varscan2
- SFSWAP | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1322718182, COSV55520068; called by muse, mutect2, varscan2
- SGIP1 | c.165del p.V56Ffs*81 | Frame Shift Del (DEL) | VAF 63/169 reads (37%) | catalogued as rs1394139864; called by mutect2, pindel, varscan2
- SHISAL2A | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV68979417, COSV68979782; called by muse, mutect2, varscan2
- SHMT1 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 43/89 reads (48%) | catalogued as rs889650535, COSV57397734; called by muse, mutect2, varscan2
- SHPRH | c.783A>C p.E261D | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.04); catalogued as COSV51605343; called by muse, mutect2
- SHROOM2 | c.4544C>T p.A1515V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66604966; called by muse, mutect2, varscan2
- SHTN1 | c.562_563del p.V188Ffs*7 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs1471668474; called by mutect2, pindel, varscan2
- SIPA1L1 | c.1416G>T p.L472F | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.854); catalogued as COSV62168804, COSV62171742; called by muse, mutect2, varscan2
- SLAMF9 | c.577del p.D193Tfs*56 | Frame Shift Del (DEL) | VAF 43/124 reads (35%) | catalogued as rs747840319; called by mutect2, pindel, varscan2
- SLC12A5 | c.2364del p.L789Cfs*38 (on ENST00000454036 / NM_001134771.2; = p.L766Cfs*38 on NM_020708.5) | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs1568866957; called by mutect2, pindel, varscan2
- SLC16A14 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54617066; called by muse, mutect2, varscan2
- SLC22A3 | c.906T>A p.D302E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV51710521; called by muse, mutect2, varscan2
- SLC22A9 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV54166076; called by muse, mutect2, varscan2
- SLC25A15 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV58556652; called by muse, mutect2, varscan2
- SLC25A23 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs777706742, COSV51190532; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 60/146 reads (41%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC25A51 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54252282; called by muse, mutect2, varscan2
- SLC2A5 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs201668362, COSV66235684; called by muse, mutect2, varscan2
- SLC35C1 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as rs754362783, COSV58479491; called by mutect2, varscan2
- SLC38A10 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs747917000, COSV55843141; called by muse, mutect2, varscan2
- SLC39A6 | c.1465+1G>A p.X489_splice | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as rs751990520, COSV52367961; called by muse, mutect2, varscan2
- SLC5A4 | c.1751A>T p.D584V | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56668805, COSV56674464; called by muse, mutect2, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLC9A1 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs749090428, COSV56051500; called by muse, mutect2, varscan2
- SLCO3A1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV59225715; called by muse, varscan2
- SMARCA4 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs1568471266, COSV60788221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC1A | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs781862992, COSV59127978; called by muse, mutect2, varscan2
- SNRPC | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 28/61 reads (46%) | catalogued as COSV55074874; called by muse, mutect2, varscan2
- SOGA3 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV64105257; called by muse, mutect2, varscan2
- SORCS1 | c.2225G>A p.C742Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53845299; called by muse, mutect2, varscan2
- SP3 | c.2245G>T p.G749* | Nonsense Mutation (SNP) | VAF 69/159 reads (43%) | catalogued as COSV59466425; called by muse, mutect2, varscan2
- SPATA31E1 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754518582, COSV57789765; called by muse, mutect2, varscan2
- SPEG | c.7955C>T p.A2652V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as COSV56664241; called by muse, mutect2, varscan2
- SPINK5 | c.2241-2A>G p.X747_splice | Splice Site (SNP) | VAF 34/81 reads (42%) | catalogued as COSV56249644; called by muse, mutect2, varscan2
- SPOCK1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs776228974, COSV56438411; called by muse, mutect2
- SPTB | c.2805-1G>A p.X935_splice | Splice Site (SNP) | VAF 12/22 reads (55%) | catalogued as COSV67630125; called by muse, mutect2, varscan2
- SPTBN5 | c.3064C>A p.Q1022K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV58017217; called by muse, mutect2, varscan2
- SRSF11 | c.338-1G>T p.X113_splice | Splice Site (SNP) | VAF 37/79 reads (47%) | catalogued as COSV63936710; called by muse, mutect2, varscan2
- SSH2 | c.2560G>T p.G854W | Missense Mutation (SNP) | VAF 105/219 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV52167313; called by muse, mutect2, varscan2
- STAG3 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 309/811 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV57927945; called by muse, mutect2, varscan2
- STC1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as rs201521623; called by muse, mutect2, varscan2
- STIP1 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV59438461; called by muse, mutect2, varscan2
- STPG1 | c.445G>A p.A149T (on ENST00000337248 / NM_001199013.2; = p.A102T on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50217942; called by muse, mutect2, varscan2
- STRC | c.461del p.P154Lfs*30 | Frame Shift Del (DEL) | VAF 35/178 reads (20%) | catalogued as rs1411667337; called by mutect2, pindel, varscan2
- STRIP2 | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV50803409; called by muse, mutect2, varscan2
- STS | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370888998, COSV54266314; called by muse, mutect2, varscan2
- SUFU | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763813479, COSV64014024; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs747003550; called by mutect2, varscan2
- SUPV3L1 | c.1800T>G p.N600K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV62844707; called by muse, mutect2
- SUSD1 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.357); catalogued as COSV62582403; called by muse, mutect2, varscan2
- SV2A | c.1259G>T p.W420L | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as rs199550214, COSV64964338; called by muse, mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 50/100 reads (50%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYDE1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1371727331, COSV54617791; called by muse, mutect2, varscan2
- SYNJ1 | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59144873; called by muse, mutect2, varscan2
- SYTL3 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as COSV51908380; called by muse, mutect2, varscan2
- SZT2 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746376950, COSV100987112; called by muse, mutect2, varscan2
- SZT2 | c.2984T>C p.L995P | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65167647; called by muse, mutect2, varscan2
- TAF1 | c.3053G>C p.R1018P (on ENST00000373790 / NM_138923.4; = p.R1039P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52108309, COSV52130397; called by muse, mutect2, varscan2
- TANC1 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs757915552, COSV55083923; called by muse, mutect2, varscan2
- TBC1D16 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs1453608590, COSV60475775; called by muse, mutect2, varscan2
- TBC1D9B | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208719642, COSV62280972; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 72/172 reads (42%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF4 | c.1786A>G p.K596E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV61891378; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 77/161 reads (48%) | catalogued as rs745872748; called by mutect2, varscan2
- TCN2 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.199); catalogued as COSV53190769; called by muse, mutect2, varscan2
- TCTE1 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs370339969; called by muse, mutect2, varscan2
- TECPR1 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65782707; called by muse, mutect2, varscan2
- TEKT5 | c.1288A>G p.K430E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV51586914; called by muse, mutect2, varscan2
- TEX11 | c.2361C>G p.H787Q (on ENST00000344304; = p.H772Q on NM_031276.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV60227002; called by muse, mutect2, varscan2
- TFAP2E | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759784927, COSV64696784; called by muse, mutect2, varscan2
- TG | c.2873T>C p.L958P | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55066763; called by muse, mutect2, varscan2
- THOC2 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 173/391 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV55541405; called by muse, mutect2, varscan2
- THSD4 | c.901T>C p.C301R | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55962675; called by muse, mutect2, varscan2
- THSD7B | c.4663C>T p.R1555* (on ENST00000272643; = p.R1553* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs754709145, COSV55659408; called by muse, mutect2, varscan2
- TIAM1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54539755; called by muse, mutect2, varscan2
- TLR3 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV57167705; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMC2 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.298); catalogued as COSV62650187; called by muse, mutect2, varscan2
- TMC5 | c.1336G>A p.V446I (on ENST00000396229 / NM_001105248.1; = p.V200I on NM_024780.5) | Missense Mutation (SNP) | VAF 164/327 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs199934900, COSV54901345; called by muse, mutect2, varscan2
- TMEM115 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1462393671, COSV51702300; called by muse, mutect2, varscan2
- TMEM81 | c.62T>C p.L21S | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1312012101, COSV52703044; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV59419924; called by muse, mutect2, varscan2
- TNIK | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52675217; called by muse, mutect2, varscan2
- TNPO2 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV63507627; called by muse, mutect2, varscan2
- TOR1B | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV52212494; called by muse, mutect2, varscan2
- TP73 | c.1196+1del p.X399_splice | Splice Site (DEL) | VAF 4/10 reads (40%) | catalogued as COSV60698948, COSV60705486; called by mutect2, varscan2
- TRAM2 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs377045665; called by muse, mutect2, varscan2
- TRIM61 | c.429dup p.L144Tfs*16 | Frame Shift Ins (INS) | VAF 65/357 reads (18%) | catalogued as rs747284694; called by mutect2, varscan2
- TSSK1B | c.900del p.E301Nfs*101 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as COSV101180989, COSV66816083; called by mutect2, pindel, varscan2
- TTC39C | c.1288G>A p.V430M (on ENST00000317571 / NM_001135993.2; = p.V369M on NM_153211.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV58215836; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TUSC3 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as rs1206273286, COSV65878180; called by muse, mutect2, varscan2
- TWSG1 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV50814655; called by muse, mutect2, varscan2
- TYK2 | c.3334A>G p.I1112V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs762714067, COSV53385130; called by muse, mutect2, varscan2
- UBAC1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV65613753; called by muse, mutect2, varscan2
- UBR5 | c.5561G>A p.R1854H | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs773575916, COSV55281256; called by muse, mutect2, varscan2
- UBXN6 | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs765934867, COSV56678278; called by muse, mutect2
- UHRF1BP1 | c.2999C>T p.T1000I | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51953066; called by muse, mutect2
- UHRF2 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52791040; called by muse, mutect2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 120/185 reads (65%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- USP31 | c.3224G>A p.S1075N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.272); catalogued as COSV54849787; called by muse, mutect2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 160/400 reads (40%) | catalogued as rs761528888; called by mutect2, varscan2
- UTP25 | c.1794del p.F598Lfs*2 | Frame Shift Del (DEL) | VAF 33/93 reads (35%) | catalogued as rs1558055503; called by mutect2, pindel, varscan2
- UTRN | c.10178C>T p.A3393V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs144906188; called by muse, mutect2, varscan2
- VARS1 | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65154807; called by muse, mutect2, varscan2
- VAV1 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.986); catalogued as rs1424857566, COSV58379504; called by muse, mutect2, varscan2
- VIPAS39 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 154/367 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV53631151; called by muse, mutect2, varscan2
- VPS26C | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs750443085, COSV55705146; called by muse, mutect2, varscan2
- VPS35 | c.1307T>C p.M436T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV54477236; called by muse, mutect2
- VSTM2A | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56492364; called by muse, mutect2, varscan2
- WDFY3 | c.10471C>T p.Q3491* | Nonsense Mutation (SNP) | VAF 70/148 reads (47%) | catalogued as COSV55694540; called by muse, mutect2, varscan2
- WDR12 | c.536T>G p.V179G | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53686515; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR7 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV54348934; called by muse, mutect2, varscan2
- WSCD2 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1282939739, COSV54578707; called by muse, mutect2, varscan2
- XRN1 | c.4663A>G p.I1555V | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as rs1382578150, COSV53808575; called by muse, mutect2, varscan2
- YAE1 | c.534A>G p.I178M | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56232688, COSV56233054; called by muse, mutect2
- ZAN | c.6812A>C p.D2271A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV61805677; called by muse, mutect2, varscan2
- ZC3H12C | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.978); catalogued as COSV53706902; called by muse, mutect2, varscan2
- ZFAT | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs780555024, COSV64735229; called by muse, mutect2, varscan2
- ZFHX3 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as rs920797808, COSV51710323; called by muse, mutect2, varscan2
- ZMYM2 | c.2601G>A p.M867I | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV67032621; called by muse, mutect2, varscan2
- ZMYND8 | c.1904del p.K635Sfs*14 (on ENST00000311275 / NM_001363741.2; = p.K655Sfs*14 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 93/208 reads (45%) | catalogued as rs776813452; called by mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 54/131 reads (41%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF142 | c.3445C>T p.P1149S (on ENST00000411696 / NM_001379660.1; = p.P949S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV68743058; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 56/130 reads (43%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF366 | c.1886A>C p.E629A | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV59214071; called by muse, mutect2, varscan2
- ZNF431 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60671828; called by muse, varscan2
- ZNF461 | c.871C>G p.H291D | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64452989; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 36/92 reads (39%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF557 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.916); catalogued as COSV53273045; called by muse, mutect2, varscan2
- ZNF585B | c.1069A>T p.T357S | Missense Mutation (SNP) | VAF 182/393 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.096); catalogued as COSV57214680; called by muse, mutect2, varscan2
- ZNF587 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs778612898, COSV57146880; called by muse, mutect2
- ZNF622 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as COSV58073591; called by muse, mutect2, varscan2
- ZNF675 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs747896801, COSV63095129; called by muse, mutect2, varscan2
- ZNF93 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.038); catalogued as COSV59374264; called by muse, mutect2, varscan2
- ZSWIM3 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV54845445; called by muse, mutect2, varscan2
- ACSL4 | c.1821-3del | Splice Region (DEL) | VAF 59/169 reads (35%) | called by mutect2, pindel, varscan2
- APOBEC1 | c.207dup p.F70Ifs*32 | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | called by mutect2, varscan2
- ATF7IP | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 68/183 reads (37%) | called by mutect2, pindel, varscan2
- BCHE | c.626del p.N209Ifs*2 | Frame Shift Del (DEL) | VAF 62/153 reads (41%) | called by mutect2, pindel, varscan2
- BCL9 | c.2726del p.P909Lfs*57 | Frame Shift Del (DEL) | VAF 73/196 reads (37%) | called by mutect2, pindel, varscan2
- BRINP2 | c.1154del p.K385Rfs*130 | Frame Shift Del (DEL) | VAF 76/226 reads (34%) | called by mutect2, pindel, varscan2
- C2orf42 | c.1230del p.K410Nfs*38 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- CAPRIN2 | c.286del p.E96Kfs*6 | Frame Shift Del (DEL) | VAF 94/224 reads (42%) | called by mutect2, pindel, varscan2
- CCAR1 | c.3184dup p.T1062Nfs*3 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- CDH16 | c.1107del p.N370Ifs*9 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- CDH26 | c.966dup p.H323Afs*3 | Frame Shift Ins (INS) | VAF 41/101 reads (41%) | called by mutect2, pindel, varscan2
- CDHR3 | c.1642dup p.S548Kfs*11 | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- CEP68 | c.700del p.Q234Rfs*9 | Frame Shift Del (DEL) | VAF 43/107 reads (40%) | called by mutect2, pindel, varscan2
- CEP85L | c.1653dup p.L552Tfs*2 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- CERK | c.155_156del p.V52Afs*4 | Frame Shift Del (DEL) | VAF 44/150 reads (29%) | called by pindel, varscan2
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- CHDH | c.1419del p.F473Lfs*26 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- CIITA | c.492del p.T165Lfs*3 | Frame Shift Del (DEL) | VAF 84/242 reads (35%) | called by pindel, varscan2
- CNP | c.1073del p.G358Afs*10 | Frame Shift Del (DEL) | VAF 29/76 reads (38%) | called by mutect2, pindel, varscan2
- COL8A1 | c.1795del p.H599Mfs*24 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- COLEC12 | c.1379del p.P460Lfs*186 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- COX18 | c.741del p.I247Mfs*20 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- COX8C | c.156del p.F52Lfs*5 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- CRMP1 | c.1685del p.P562Lfs*21 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- CTIF | c.1752del p.I585Sfs*12 | Frame Shift Del (DEL) | VAF 38/100 reads (38%) | called by mutect2, pindel, varscan2
- DCAF8 | c.445del p.R149Dfs*67 | Frame Shift Del (DEL) | VAF 53/132 reads (40%) | called by mutect2, pindel, varscan2
- DHX34 | c.1542del p.Y515Tfs*18 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, pindel, varscan2
- DLK1 | c.479del p.P160Lfs*50 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- DTX2 | c.692del p.P231Hfs*31 | Frame Shift Del (DEL) | VAF 52/108 reads (48%) | called by mutect2, varscan2
- DUSP3 | c.347del p.K116Rfs*19 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel
- EFCAB5 | c.2041del p.S681Vfs*8 | Frame Shift Del (DEL) | VAF 91/228 reads (40%) | called by mutect2, pindel, varscan2
- EGR2 | c.1337dup p.V447Rfs*11 | Frame Shift Ins (INS) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- ERG | c.1359del p.F453Lfs*59 (on ENST00000398919 / NM_001243428.1; = p.F429Lfs*59 on NM_004449.4) | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | called by mutect2, pindel, varscan2
- EYA4 | c.1218del p.M407Wfs*3 (on ENST00000531901 / NM_001301013.1; = p.M401Wfs*3 on NM_004100.5) | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | called by mutect2, pindel, varscan2
- F13A1 | c.397del p.A133Pfs*5 | Frame Shift Del (DEL) | VAF 64/165 reads (39%) | called by mutect2, pindel, varscan2
- FOXJ3 | c.1246del p.Q416Sfs*20 | Frame Shift Del (DEL) | VAF 77/225 reads (34%) | called by mutect2, pindel, varscan2
- FZD1 | c.1637_1638del p.V546Afs*60 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2
- GALNT15 | c.409dup p.A137Gfs*2 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | called by pindel, varscan2
- GRIK5 | c.2357del p.G786Afs*? | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- HECW1 | c.1359del p.S454Vfs*75 | Frame Shift Del (DEL) | VAF 11/19 reads (58%) | called by mutect2, varscan2
- HSPB8 | c.266del p.P89Hfs*12 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | called by mutect2, varscan2
- IGSF9B | c.1260del p.Y421Ifs*37 | Frame Shift Del (DEL) | VAF 11/20 reads (55%) | called by mutect2, varscan2
- IL5 | c.176del p.N59Ifs*13 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- INTS2 | c.3300del p.F1100Lfs*26 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel
- ITPR3 | c.3559del p.E1187Sfs*3 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- KITLG | c.375del p.K125Nfs*31 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | called by mutect2, pindel, varscan2
- KLC2 | c.1290del p.Y431Mfs*13 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, pindel, varscan2
- LIMS1 | c.787+4_787+7del p.X263_splice | Splice Site (DEL) | VAF 44/116 reads (38%) | called by mutect2, varscan2
- LRRIQ1 | c.1451del p.N484Mfs*4 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, varscan2
- MAD2L1 | c.498del p.K166Nfs*28 | Frame Shift Del (DEL) | VAF 29/72 reads (40%) | called by mutect2, pindel, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- NAA40 | c.394del p.D132Mfs*37 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- NFATC2 | c.2543del p.P848Rfs*8 | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | called by mutect2, pindel, varscan2
- NIPBL | c.4269dup p.V1424Cfs*6 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- NLRP7 | c.86del p.L29Yfs*39 | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- NSD1 | c.3473del p.K1158Sfs*6 | Frame Shift Del (DEL) | VAF 70/187 reads (37%) | called by mutect2, pindel, varscan2
- OR52E2 | c.947del p.K316Rfs*5 | Frame Shift Del (DEL) | VAF 53/135 reads (39%) | called by mutect2, pindel, varscan2
- OR6C68 | c.916del p.I306Lfs*5 | Frame Shift Del (DEL) | VAF 60/113 reads (53%) | called by mutect2, varscan2
- OTUD7B | c.2153del p.G718Vfs*110 | Frame Shift Del (DEL) | VAF 53/120 reads (44%) | called by mutect2, pindel, varscan2
- OXCT2 | c.1490del p.K497Rfs*74 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- PCSK7 | c.147_148insT p.G50Wfs*15 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel
- PLCZ1 | c.983dup p.L329Vfs*23 | Frame Shift Ins (INS) | VAF 21/68 reads (31%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | called by mutect2, pindel, varscan2
- PLXND1 | c.3994_3997del p.D1332* | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by pindel, varscan2
- POLR2A | c.1107del p.D370Tfs*19 | Frame Shift Del (DEL) | VAF 40/155 reads (26%) | called by mutect2, pindel, varscan2
- POLR3E | c.1782del p.G595Afs*51 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- POU2F2 | c.840dup p.N281Qfs*221 (on ENST00000526816 / NM_001207025.3; = p.N265Qfs*221 on NM_002698.5) | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- PRCC | c.1138del p.Q380Rfs*47 | Frame Shift Del (DEL) | VAF 52/122 reads (43%) | called by mutect2, varscan2
- PRNP | c.586del p.E196Rfs*10 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | called by mutect2, pindel, varscan2
- RAB40A | c.765dup p.V256Sfs*55 | Frame Shift Ins (INS) | VAF 85/266 reads (32%) | called by mutect2, pindel, varscan2
- RB1 | c.1848dup p.G617Rfs*36 | Frame Shift Ins (INS) | VAF 66/155 reads (43%) | called by mutect2, pindel, varscan2
- RNF111 | c.2318del p.P773Hfs*44 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- RNF213 | c.8444del p.P2815Hfs*29 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- RPRD1B | c.946del p.L316Cfs*35 | Frame Shift Del (DEL) | VAF 68/190 reads (36%) | called by mutect2, varscan2
- RTCB | c.736del p.M246Wfs*11 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by pindel, varscan2
- RTN4 | c.2007del p.V670Yfs*4 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- SCAF11 | c.2558del p.K853Rfs*46 | Frame Shift Del (DEL) | VAF 117/334 reads (35%) | called by mutect2, pindel, varscan2
- SEC24D | c.1414del p.I472Ffs*28 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- SEMA4F | c.1009del p.A337Lfs*18 | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | called by mutect2, pindel, varscan2
- SLC22A16 | c.1693del p.T565Rfs*21 | Frame Shift Del (DEL) | VAF 165/444 reads (37%) | called by mutect2, pindel, varscan2
- SWAP70 | c.825dup p.L276Sfs*6 | Frame Shift Ins (INS) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- THYN1 | c.581del p.N194Ifs*15 | Frame Shift Del (DEL) | VAF 57/140 reads (41%) | called by mutect2, pindel, varscan2
- TLR5 | c.603del p.F201Lfs*20 | Frame Shift Del (DEL) | VAF 72/188 reads (38%) | called by mutect2, pindel, varscan2
- TRIOBP | c.990del p.R331Gfs*548 | Frame Shift Del (DEL) | VAF 138/390 reads (35%) | called by mutect2, pindel, varscan2
- TTN | c.33642del p.V11215Wfs*72 (on ENST00000591111; = p.V10288Wfs*72 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/55 reads (55%) | called by mutect2, varscan2
- UBA6 | c.897del p.F299Lfs*8 | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | called by mutect2, varscan2
- UBP1 | c.137del p.F46Sfs*22 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | called by mutect2, pindel, varscan2
- USP47 | c.1513_1515del p.Y505del (on ENST00000399455 / NM_001372095.1; = p.Y417del on NM_017944.4 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 66/170 reads (39%) | called by pindel, varscan2
- WASHC2C | c.1032del p.K345Sfs*2 | Frame Shift Del (DEL) | VAF 118/429 reads (28%) | called by mutect2, pindel, varscan2
- WDR38 | c.426_427del p.L143Sfs*5 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2
- WDR48 | c.1276dup p.T426Nfs*10 | Frame Shift Ins (INS) | VAF 32/98 reads (33%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.8777del p.P2926Rfs*28 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- ZFP3 | c.202_203del p.D68Lfs*9 | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | called by pindel, varscan2
- ZFYVE16 | c.287dup p.N96Kfs*6 | Frame Shift Ins (INS) | VAF 57/135 reads (42%) | called by mutect2, varscan2
- ZNF273 | c.847del p.I283Ffs*28 | Frame Shift Del (DEL) | VAF 56/150 reads (37%) | called by mutect2, pindel, varscan2
- ZNF322 | c.375dup p.F126Ifs*5 | Frame Shift Ins (INS) | VAF 75/383 reads (20%) | called by mutect2, pindel, varscan2
- ZNF430 | c.320del p.P107Qfs*17 | Frame Shift Del (DEL) | VAF 74/215 reads (34%) | called by mutect2, pindel, varscan2
- ZNF608 | c.4137_4138del p.P1380Rfs*24 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by pindel, varscan2
- ZNF687 | c.2611dup p.R871Kfs*34 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- ZNF800 | c.267del p.K89Nfs*17 | Frame Shift Del (DEL) | VAF 54/136 reads (40%) | called by mutect2, pindel, varscan2
- ABCC2 | c.1155C>T p.C385= | Silent (SNP) | VAF 153/322 reads (48%) | catalogued as rs1227257975, COSV64970645; called by muse, mutect2, varscan2
- ACTN2 | c.958C>T p.L320= | Silent (SNP) | VAF 127/253 reads (50%) | catalogued as COSV63972541; called by muse, mutect2, varscan2
- ADAM9 | c.1854C>T p.N618= | Silent (SNP) | VAF 66/123 reads (54%) | catalogued as rs375191198; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1776C>T p.G592= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs749692173, COSV54996925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD27 | c.1050C>T p.Y350= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV60129256; called by muse, mutect2, varscan2
- ANP32E | c.153T>C p.N51= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV58481438; called by muse, mutect2, varscan2
- ARHGEF15 | c.1930T>C p.L644= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV62724481; called by muse, mutect2, varscan2
- ARID5B | c.3090A>G p.A1030= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs1310249320, COSV54415035; called by muse, mutect2, varscan2
- ARSJ | c.1203T>C p.Y401= | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as rs1273399411, COSV59536891; called by muse, mutect2, varscan2
- ASL | c.771C>T p.A257= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs375586912; called by muse, mutect2, varscan2
- ATG2B | c.2883C>A p.I961= | Silent (SNP) | VAF 59/142 reads (42%) | catalogued as COSV63421923; called by muse, mutect2, varscan2
- ATRX | c.4389G>A p.E1463= | Silent (SNP) | VAF 297/637 reads (47%) | catalogued as COSV64872267; called by muse, mutect2, varscan2
- ATXN2L | c.627C>T p.T209= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV57366446; called by muse, mutect2, varscan2
- B3GAT1 | c.654C>T p.P218= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs751267144, COSV56995354; called by muse, varscan2
- BCOR | c.3747G>A p.G1249= (on ENST00000378444 / NM_001123385.2; = p.G1215= on NM_017745.6) | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as COSV60701370; called by muse, mutect2, varscan2
- BRD3 | c.1764C>T p.P588= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs200686859, COSV57701771; called by muse, mutect2, varscan2
- BTBD3 | c.801G>A p.Q267= | Silent (SNP) | VAF 67/149 reads (45%) | catalogued as COSV54778021; called by muse, mutect2, varscan2
- BTBD3 | c.1146C>A p.A382= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as COSV54778029; called by muse, mutect2, varscan2
- C6orf47 | c.882G>A p.L294= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as COSV63263623; called by muse, mutect2, varscan2
- CCDC185 | c.1828C>T p.L610= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV64820389; called by muse, mutect2, varscan2
- CCDC57 | c.570T>A p.R190= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV66432886; called by muse, mutect2, varscan2
- CD9 | c.534G>A p.V178= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV50530004; called by muse, mutect2, varscan2
- CELSR2 | c.8016G>A p.S2672= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs758244777, COSV54767659; called by muse, mutect2, varscan2
- CHST5 | c.1113C>T p.C371= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs770975222, COSV60337353; called by muse, mutect2, varscan2
- CIT | c.4533C>A p.S1511= | Silent (SNP) | VAF 61/128 reads (48%) | catalogued as COSV55861655, COSV55864148; called by muse, mutect2, varscan2
- CLCN4 | c.1995G>A p.Q665= | Silent (SNP) | VAF 69/155 reads (45%) | catalogued as COSV66465334; called by muse, mutect2, varscan2
- CLSTN1 | c.465C>T p.N155= (on ENST00000377298 / NM_001009566.3; = p.N145= on NM_014944.4) | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs750019286, COSV63646850; called by muse, mutect2, varscan2
- CNTN5 | c.2421C>T p.F807= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs751788662, COSV54285581; called by muse, mutect2
- COBL | c.1389T>C p.S463= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV54339570; called by muse, mutect2, varscan2
- COL18A1 | c.1719C>T p.F573= (on ENST00000359759 / NM_130444.3; = p.F338= on NM_030582.4) | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs377547341; called by muse, mutect2, varscan2
- COL3A1 | c.2412C>T p.G804= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs772579642, COSV58582814; called by muse, mutect2, varscan2
- COMMD5 | c.525C>T p.S175= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs139395946, COSV57382780; called by muse, mutect2, varscan2
- CPPED1 | c.828C>T p.H276= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs746018723, COSV55495918; called by muse, mutect2, varscan2
- CSNK1A1L | c.195G>A p.T65= | Silent (SNP) | VAF 74/169 reads (44%) | catalogued as COSV65789341; called by muse, mutect2, varscan2
- CYP2F1 | c.132G>A p.L44= | Silent (SNP) | VAF 339/710 reads (48%) | catalogued as COSV58526779; called by mutect2, varscan2
- DAPK1 | c.2088G>A p.S696= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as rs770475590, COSV63784825; called by muse, mutect2, varscan2
- DIP2C | c.1437G>A p.P479= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs1416491391, COSV55148032; called by muse, mutect2, varscan2
- DISC1 | c.1095T>C p.V365= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV54401595; called by muse, mutect2, varscan2
- DRD5 | c.1284C>T p.D428= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs201092734, COSV58576916; called by muse, mutect2, varscan2
- EPX | c.1933C>A p.R645= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV56595245, COSV56597919; called by muse, mutect2, varscan2
- ESYT1 | c.2391G>A p.A797= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs144130518; called by muse, mutect2, varscan2
- EXOC3 | c.1065C>T p.N355= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs989531810, COSV59265687; called by muse, mutect2, varscan2
- FANCI | c.2850T>C p.S950= (on ENST00000310775 / NM_001376911.1; = p.S890= on NM_018193.3) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV55523972; called by muse, mutect2, varscan2
- FAT1 | c.10308C>T p.N3436= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as rs745964428, COSV71672215; called by muse, mutect2, varscan2
- FAT3 | c.11727C>T p.G3909= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV53081349; called by muse, mutect2, varscan2
- FCGBP | c.5406G>A p.T1802= | Silent (SNP) | VAF 93/237 reads (39%) | called by muse, mutect2, varscan2
- FGA | c.2103C>T p.D701= | Silent (SNP) | VAF 92/209 reads (44%) | catalogued as rs148411201; called by muse, mutect2, varscan2
- FNIP1 | c.2505C>T p.F835= | Silent (SNP) | VAF 89/231 reads (39%) | catalogued as rs373191619, COSV57194251; called by muse, mutect2, varscan2
- FOXD4L5 | c.279G>A p.P93= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as rs757912448, COSV66240137; called by mutect2, varscan2
- FRMPD2 | c.906G>A p.L302= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV59715704; called by muse, mutect2, varscan2
- FTSJ3 | c.1563G>A p.L521= | Silent (SNP) | VAF 292/588 reads (50%) | catalogued as COSV63789446; called by muse, varscan2
- GIMAP1 | c.684G>A p.A228= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1202671941, COSV56187236; called by muse, mutect2, varscan2
- GPATCH1 | c.576C>T p.G192= | Silent (SNP) | VAF 75/162 reads (46%) | catalogued as rs1435927120, COSV50111647; called by muse, mutect2, varscan2
- GPATCH3 | c.1197C>T p.I399= | Silent (SNP) | VAF 112/222 reads (50%) | catalogued as rs761727096, COSV64651656; called by muse, mutect2, varscan2
- GPR132 | c.24C>T p.N8= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs140169579; called by muse, mutect2, varscan2
- GPR161 | c.567G>A p.T189= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as rs1313058850, COSV54788160, COSV99607243; called by muse, mutect2, varscan2
- GREB1 | c.3552G>A p.G1184= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs776138840, COSV52181851, COSV52197674; called by muse, mutect2, varscan2
- GRIK3 | c.981C>T p.Y327= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs535104528, COSV66136153; called by muse, mutect2, varscan2
- HAS1 | c.1125G>A p.Q375= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55786372; called by muse, mutect2, varscan2
- IGHV3-43 | c.141C>A p.T47= | Silent (SNP) | VAF 246/524 reads (47%) | called by muse, mutect2, varscan2
- IL12A | c.504C>T p.Y168= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV59758828; called by muse, mutect2
- IL12RB2 | c.1476C>T p.Y492= | Silent (SNP) | VAF 60/243 reads (25%) | catalogued as rs746380634, COSV52020661; called by muse, mutect2, varscan2
- IL17RE | c.603C>T p.S201= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as rs80297306; called by muse, mutect2, varscan2
- IL1RL2 | c.996G>A p.P332= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs373341199; called by muse, mutect2, varscan2
- IL1RL2 | c.1650G>A p.L550= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs971683168, COSV51813269; called by muse, mutect2, varscan2
- IL2RG | c.1098G>A p.K366= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV52147376; called by muse, mutect2, varscan2
- IL7 | c.252T>C p.A84= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV55673128; called by muse, mutect2, varscan2
- IRF5 | c.61C>T p.L21= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs1359043872, COSV50856803; called by muse, mutect2, varscan2
- ITIH6 | c.693G>A p.L231= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV54486978; called by muse, mutect2, varscan2
- ITPK1 | c.288G>A p.P96= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs755820884, COSV50893732; called by muse, mutect2, varscan2
- KCNA3 | c.1356A>G p.P452= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1332569424, COSV63901075; called by muse, mutect2, varscan2
- KCNA3 | c.724C>T p.L242= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV63900905; called by muse, mutect2, varscan2
- KCNT2 | c.1329C>T p.A443= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV54066521; called by muse, mutect2, varscan2
- KIF21B | c.3555C>T p.D1185= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV59753132; called by muse, mutect2, varscan2
- KMT2B | c.7755C>T p.H2585= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs562759628, COSV53073849; ClinVar: likely benign; called by muse, mutect2
- KRT33B | c.1069C>A p.R357= | Silent (SNP) | VAF 89/228 reads (39%) | catalogued as rs769794586, COSV52440355; called by muse, mutect2, varscan2
- L1CAM | c.1638C>A p.S546= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV62827043; called by muse, mutect2, varscan2
- LAMA3 | c.4182C>T p.S1394= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs370165878; called by muse, mutect2, varscan2
- LRIG2 | c.399A>G p.P133= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV63160986; called by muse, mutect2, varscan2
- LRRC8B | c.2160G>T p.G720= | Silent (SNP) | VAF 102/249 reads (41%) | catalogued as rs766697683, COSV58373277; called by muse, mutect2, varscan2
- MCM6 | c.639T>A p.A213= | Silent (SNP) | VAF 77/203 reads (38%) | catalogued as COSV51465064; called by muse, mutect2, varscan2
- MCTP1 | c.1419C>T p.S473= | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as COSV56505778; called by muse, mutect2, varscan2
- MED15 | c.1860G>A p.P620= (on ENST00000263205 / NM_001003891.3; = p.P580= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs772860212, COSV53027176; called by muse, mutect2, varscan2
- MICAL2 | c.3834G>A p.S1278= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as rs763990582, COSV56284348; called by muse, mutect2, varscan2
- MICU3 | c.495G>A p.P165= | Silent (SNP) | VAF 82/159 reads (52%) | catalogued as rs763504827, COSV58845017; called by muse, mutect2, varscan2
- MLLT1 | c.165G>A p.L55= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs773276134, COSV53129360; called by muse, mutect2, varscan2
- MMP2 | c.867G>A p.Q289= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1442995054, COSV54599294; called by muse, mutect2, varscan2
- MMP27 | c.1452A>G p.S484= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV52779936; called by muse, mutect2, varscan2
- MON2 | c.4137G>A p.Q1379= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as rs1185699009, COSV54803724; called by muse, mutect2, varscan2
- MPI | c.102T>C p.S34= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV60396403; called by muse, mutect2, varscan2
- MRPL2 | c.606G>T p.R202= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV52433762; called by muse, mutect2, varscan2
- MRPS15 | c.423A>G p.E141= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as COSV64152170; called by muse, mutect2, varscan2
- MUC16 | c.1806G>A p.Q602= | Silent (SNP) | VAF 113/217 reads (52%) | catalogued as COSV67448466; called by muse, mutect2, varscan2
- MYH7B | c.3351T>G p.A1117= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV53417057; called by muse, mutect2, varscan2
- MYO16 | c.3777C>T p.A1259= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs368440442, COSV62746055; called by muse, mutect2, varscan2
- MYO19 | c.1494C>T p.S498= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs753067672; called by muse, mutect2, varscan2
- MYO7B | c.531C>T p.T177= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV67345016; called by muse, mutect2, varscan2
- N4BP3 | c.540C>T p.G180= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs758855387, COSV51061856; called by muse, mutect2, varscan2
- NAALADL1 | c.2088A>G p.L696= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV57245983; called by muse, mutect2, varscan2
- NCOR1 | c.2793G>A p.Q931= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs1374585908, COSV51963055; called by muse, mutect2, varscan2
- NPAS3 | c.990C>T p.C330= (on ENST00000356141 / NM_001164749.2; = p.C298= on NM_022123.3) | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as rs150383378; called by muse, mutect2, varscan2
- NRSN1 | c.396G>A p.G132= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as COSV65893715; called by muse, mutect2, varscan2
- ODF2 | c.2418C>T p.N806= (on ENST00000434106 / NM_153433.2; = p.N782= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as rs779037856, COSV59406573; called by muse, mutect2, varscan2
- OPN1SW | c.225C>T p.N75= | Silent (SNP) | VAF 85/307 reads (28%) | catalogued as rs779743701, COSV50821272; called by muse, mutect2, varscan2
- OR2M5 | c.606C>T p.C202= | Silent (SNP) | VAF 280/677 reads (41%) | catalogued as rs1416063980, COSV63545801; called by muse, mutect2, varscan2
- OSBPL9 | c.1899T>C p.Y633= | Silent (SNP) | VAF 79/193 reads (41%) | catalogued as COSV61401976; called by muse, mutect2, varscan2
- PCDHA3 | c.1734C>T p.S578= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as rs1166121837, COSV63539345; called by muse, mutect2, varscan2
- PCDHGB6 | c.1611C>T p.H537= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV53906971; called by muse, mutect2, varscan2
- PCGF1 | c.387C>T p.S129= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as rs774774499, COSV52042286; called by muse, mutect2, varscan2
- PCGF5 | c.279T>C p.R93= | Silent (SNP) | VAF 190/434 reads (44%) | catalogued as COSV60237220; called by muse, mutect2, varscan2
- PGA3 | c.27G>T p.L9= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV57711480; called by muse, mutect2, varscan2
- PHF2 | c.2193T>C p.D731= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV63678987; called by muse, mutect2
- PIK3R5 | c.1548G>A p.T516= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs780537367, COSV52651094; called by muse, mutect2, varscan2
- PKHD1 | c.10887T>C p.S3629= | Silent (SNP) | VAF 106/239 reads (44%) | catalogued as COSV64382576; called by muse, mutect2, varscan2
- PLCD3 | c.2055C>T p.D685= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1336247914, COSV51958510; called by muse, mutect2, varscan2
- PLCE1 | c.2163C>T p.S721= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as rs377278909; called by muse, mutect2, varscan2
- PLIN4 | c.2859A>G p.G953= (on ENST00000301286; = p.G968= on NM_001367868.2) | Silent (SNP) | VAF 42/60 reads (70%) | catalogued as rs1487810658, COSV56686664; called by muse, mutect2, varscan2
- PNKP | c.924C>T p.C308= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs771622669, COSV55586565; called by muse, mutect2
- POLR3A | c.1803C>T p.F601= | Silent (SNP) | VAF 76/218 reads (35%) | catalogued as rs766223853, COSV64930352; called by muse, mutect2, varscan2
- PPIP5K2 | c.784C>A p.R262= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV58603093; called by muse, mutect2, varscan2
- PRDM2 | c.1497A>G p.R499= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as rs1207466918, COSV52443393; called by muse, mutect2, varscan2
68 further variants in this file (0 protein-altering or splice-affecting, 45 silent, 23 other) are not listed here.
